CCDI case PBBIZK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/dadbc7cc-40b5-481d-b038-130fd2300ab5

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 2.6 years (933 days).

Biospecimens (3 samples)
- Sample 0DB6TZ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DB6U0: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DB6U1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
